Surgical pathology report (de-identified scan), TCGA case TCGA-P6-A5OF, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site Translational Genomics Research Institute, specimen TCGA-P6-A5OF-01A (Primary Tumor).

[page 1 of 3]
Go to...

Report for [REDACTED]

TEST: Surgical Pathology
Collected Date & Time:

Result Name Results Units
Surgical Pathology SURGICAL P
SURGICAL PATHOLOGY REPORT
See Addendum

Reference Range

ICD-O-3

Carcinoma, Adrenal-cortical
8370/3
Site (R) Adrenal gland, cortex
874.D
JW 4/29/13

Patient Name: [REDACTED]
Accession # [REDACTED]
Med. Rec. #: [REDACTED]
Billing Type:
Location:
DOB: [REDACTED] (Age:
Service:
Gender: F
Billing #: [REDACTED]
Taken
Physician(s):

Specimen(s) Received

- A: Falciform ligament
- B: Gallbladder
- C: Tissue next to right common bile duct
- D: Right adrenal cortical carcinoma intracaval thrombus
- E: Gerota's fascia
- F: Liver

Pathologic Diagnosis

Falciform ligament, biopsy (A):
- Benign fibroadipose tissue.
Gallbladder, excision (B):
- Chronic cholecystitis.
- Cholelithiasis.
Tissue next to right common bile duct, biopsy (C):
- Benign fibroadipose tissue.
Adrenal gland, right and intracaval thrombus, excision (D):
- Adrenocortical carcinoma, see note.
Note: The right adrenal gland weighs 277 grams and measures 10.5 cm in greatest dimension. The neoplasm demonstrates areas of necrosis with focal venous invasion present. There is significant nuclear atypia present with frequent mitotic figures. The lesion does not appear to invade the capsule of the adrenal gland. The capsular margins of excision appear free of malignancy. There is thrombus present consisting of admixed tumor and hemorrhage. This thrombus corresponds to the clinically described intracaval thrombus. The neoplastic cells are immunoreactive for inhibin, calretinin, synaptophysin, and melan A; and non-immunoreactive for CD99. The immunohistochemical findings support the above diagnosis.
Gerota's fascia, biopsy (E):
- Benign fibroadipose tissue.
Liver, biopsy (F):
- Hepatic parenchyma with mild macrovesicular steatosis

[page 2 of 3]
and subcapsular hemorrhage.

SURGICAL PATHOLOGY CANCER CASE SUMMARY CHECKLIST:

Specimen: Adrenal gland, resection; received in formalin.

Procedure: Adrenalectomy, total.

Specimen Integrity: Intact.

Specimen Size: Greatest dimension 10.5 x 9.5 x 5.0 cm.

Specimen Laterality: Right.

Tumor Size: 10.5 cm.

Tumor Gland Weight: 277 g.

Histologic Type: Adrenocortical carcinoma.

Margins: Capsular margins are negative, neoplasm involves inferior vena cava.

Treatment Effect: Not identified.

Lymph-Vascular Invasion: Present, large and small vessel.

Perineural Invasion: Not identified.

PATHOLOGIC STAGE: Primary tumor: pT4. Region lymph nodes:

pNx. Distal metastasis: Not applicable.

NOTE: Information on pathology stage and the operative procedure is transmitted to this Institution's Cancer Registry as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen being evaluated and does not incorporate other relevant data. Pathology stage is only a component to be considered in determining the clinical stage and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

Primary Pathologist:

Addendum

The modified Weiss score of the neoplasm is 4. Modified Weiss scores of greater than 3 suggest malignancy (AJSP 2002; 26:1612).

Electronically signed Out by

Clinical History

Right adrenal cortical carcinoma.

Intraoperative Consultation

A: Falciform ligament: Benign (microscopic).

C: Tissue next to right common bile duct: Benign fibrovascular and adipose tissue (microscopic).

Gross Description

A: Received fresh for frozen section labeled "falciform ligament" is a 6.5 x 5.5 x 1.5 cm glistening yellow, lobulated adipose tissue partly surfaced by glistening tan-blue, possible peritoneum. Sectioning reveals a 1.5 x 1.0 x 0.3 cm gray-tan fibrous area. No other suspicious areas are grossly identified. No discrete masses are grossly identified. The remainder of the specimen consists of unremarkable yellow-tan fibrofatty tissue. Representative sections are submitted as labeled: "FS-A1" suspicious fibrous area in total, "FS-A2" possible peritoneum, "FS-A3" random sections (three cassettes).

B: Received in formalin labeled "gallbladder" is an intact 8.5 x 3.0 x 3.0 cm gallbladder with a 1 cm cystic duct. Within the cystic duct and gallbladder lumen is a 6.0 x 4.5 x 1.0 cm

[page 3 of 3]
aggregate of multiple yellow-green, multifaceted stones ranging from 0.2 cm to 2.0 cm. The serosa is glistening tan-blue. The adventitia is shaggy, tan-yellow. The walls have uniform thickness and average 0.1 cm. The mucosa is heterogenous, green-yellow and varies from granular to flattened. The lumen contains a moderate amount of green-yellow viscous bile. Representative sections are submitted to include the cystic duct margin inked blue (one cassette).

C: Received fresh for frozen section labeled "tissue next to right common bile duct" is a 2.0 x 1.0 x 0.3 cm aggregate of a few irregular fragments of yellow-tan fibrofatty tissues. The specimen is submitted in toto for frozen section in "FS-C1".

D: Received in formalin labeled "right adrenal cortical carcinoma intracaval thrombus" is a disrupted 277 g, 10.5 x 9.5 x 5.0 cm soft mass and a 5.0 x 5.0 x 1.0 cm aggregate of yellow-tan fibrofatty tissue. The mass is focally disrupted and previously incised. The external surface is predominantly smooth, heterogenous, yellow-pink, and multifocally shaggy, red-pink. The mass is inked black and serially sectioned revealing a heterogenous tan-red, slightly gritty cut surface. On the surface of the mass is a 5.5 x 2.0 x 0.3 cm remnant of adrenal gland with a heterogenous golden-yellow cut surface. Within the adrenal remnant is a 0.4 cm diameter, well-circumscribed rubbery nodule with a homogenous tan-pink cut surface. Sectioning through the separate aggregate of fibrofatty tissue reveals a homogenous yellow, lobulated cut surface, and a moderate amount of admixed blood clot. No discrete masses are grossly identified. Representative sections are submitted as labeled: "D1"- "D6" mass periphery and adrenal gland remnant, "D7" remainder of adrenal gland remnant and nodule in toto, "D8" separate aggregate of fibrofatty tissue, "D9"- "D10" blood clots (ten cassettes). The specimen is reviewed by

E: Received in formalin labeled "Gerota's fascia" is an 11.0 x 10.5 x 2.5 cm aggregate of multiple fragments of yellow, lobulated adipose tissue, admixed with a minimal amount of blood clot. Sectioning reveals a homogenous yellow, lobulated cut surface. No discrete masses or suspicious areas are grossly identified. Representative sections are submitted (two cassettes).

F: Received in formalin labeled "liver" is a 26 g, 7.0 x 6.5 x 1.5 cm aggregate of several fragments of disrupted and hemorrhagic hepatic tissue and yellow, lobulated adipose tissue. The specimen is serially sectioned. The hepatic tissue has a heterogenous, tan-green cut surface. The adipose tissue has a homogenous yellow, lobulated cut surface. No discrete masses are grossly identified. Representative sections are submitted as labeled: "F1"- "F2" hepatic tissue, "F3" adipose tissue (three cassettes).

Microscopic Description

Microscopic examination has been performed on all slides. The pathologic diagnosis encompasses the essential microscopic findings of this case.
Interpretation performed at

Source: NCI Genomic Data Commons file c689a168-60a1-402b-8b83-e1af432ec427 (TCGA-P6-A5OF.D03F4355-72A4-4CDF-B7BE-DDB016D69A90.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).